Somatic mutation profile of tumor specimen TCGA-L5-A8NU-01A (aliquot TCGA-L5-A8NU-01A-11D-A36J-09) from TCGA case TCGA-L5-A8NU, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen TCGA-L5-A8NU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b8ac8d76-c95b-40ff-a096-d4a6b4cad0be.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-L5-A8NU-11A (Solid Tissue Normal), aliquot TCGA-L5-A8NU-11A-11D-A36M-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/246ee543-76b9-4dfc-bc06-a358c53826bb

The open-access MAF lists 57 somatic variants for this specimen: 36 protein-altering or splice-affecting, 19 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 19, In Frame Del 1, 5'Flank 1, Splice Site 1, Nonsense Mutation 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRD1 | c.17G>A p.R6Q | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.015); catalogued as rs1269659912; called by muse, mutect2, varscan2
- CHD5 | c.931G>A p.V311M | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.027); catalogued as rs1363035377, COSV52427754, COSV99315729; called by muse, mutect2, varscan2
- CHRM2 | c.953A>G p.E318G | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV57783351; called by muse, mutect2, varscan2
- CMC1 | c.110-1G>C p.X37_splice | Splice Site (SNP) | VAF 13/82 reads (16%) | catalogued as rs1198097290; called by muse, mutect2, varscan2
- CTTNBP2 | c.187C>T p.R63W | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs752206807, COSV50488235; called by muse, mutect2, varscan2
- CYLC1 | c.251T>G p.I84S | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.44); PolyPhen benign (0.009); catalogued as rs1358418612, COSV61415383; called by muse, mutect2, varscan2
- DAPK1 | c.4000T>G p.L1334V | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.103); catalogued as rs879749139, COSV63786825; called by muse, mutect2, varscan2
- FAHD2B | c.488C>T p.A163V | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.794); catalogued as COSV55630467; called by muse, mutect2, varscan2
- GAB1 | c.421G>A p.A141T | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs775106183; called by muse, mutect2, varscan2
- HERC2 | c.9556G>A p.G3186S | Missense Mutation (SNP) | VAF 34/208 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99876917; called by muse, mutect2, varscan2
- HERC6 | c.1030G>A p.V344M | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.572); catalogued as rs1022721482; called by muse, mutect2, varscan2
- ITGAX | c.382C>T p.L128F | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV51647931; called by muse, mutect2, varscan2
- LRRC8C | c.712G>C p.A238P | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777740781; called by muse, mutect2, varscan2
- NBEA | c.4640G>A p.R1547H | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.869); catalogued as rs937005979, COSV59781101; called by muse, mutect2, varscan2
- OR7D4 | c.542C>T p.P181L | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs142332857, COSV58071798; called by muse, mutect2
- PTPRE | c.1807G>A p.E603K | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.582); catalogued as rs376366402, COSV54547347; called by muse, mutect2, varscan2
- SGSH | c.313C>T p.R105W | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.846); catalogued as rs375755239; called by muse, mutect2, varscan2
- TRHDE | c.2270C>T p.A757V | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1446950309; called by muse, mutect2
- TRPA1 | c.1064G>A p.W355* | Nonsense Mutation (SNP) | VAF 4/37 reads (11%) | catalogued as rs1417069967; called by muse, mutect2, varscan2
- WNT9B | c.460C>T p.R154W | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs746091846, COSV51520187; called by muse, mutect2, varscan2
- ZNF234 | c.1312C>T p.R438C | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.825); catalogued as rs1050998717, COSV70603787; called by muse, mutect2, varscan2
- CDH6 | c.687G>C p.R229S | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- FBXO15 | c.316C>A p.H106N | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- GNAI2 | c.860G>A p.C287Y | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.563); called by muse, mutect2, varscan2
- HNRNPA2B1 | c.841G>A p.G281R (on ENST00000354667 / NM_031243.3; = p.G269R on NM_002137.4) | Missense Mutation (SNP) | VAF 9/114 reads (8%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.887); called by muse, mutect2
- KMT2E | c.185C>T p.A62V | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- LTBP1 | c.1943A>T p.Y648F (on ENST00000404816 / NM_206943.4; = p.Y322F on NM_000627.4) | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.302); called by muse, mutect2, varscan2
- MPHOSPH8 | c.251C>G p.T84R | Missense Mutation (SNP) | VAF 6/129 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.925); called by muse, mutect2
- MTCL1 | c.3865C>G p.Q1289E (on ENST00000306329 / NM_001378206.1; = p.Q970E on NM_015210.4) | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.149); called by muse, mutect2, varscan2
- MUC16 | c.38204T>G p.L12735R | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NIFK | c.122_124del p.Q41del | In Frame Del (DEL) | VAF 11/77 reads (14%) | called by pindel, varscan2
- NRG1 | c.299A>T p.N100I | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.511); called by muse, mutect2, varscan2
- PDHA2 | c.748C>A p.L250I | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.66); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- RIBC1 | c.343G>T p.D115Y | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.577); called by muse, mutect2, varscan2
- TCP11L2 | c.801A>G p.I267M | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); called by muse, mutect2
- THSD7B | c.3680G>A p.C1227Y (on ENST00000272643; = p.C1225Y on NM_001316349.2) | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARHGAP36 | c.723T>C p.A241= | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as COSV52270709; called by muse, mutect2, varscan2
- CAVIN1 | c.609G>A p.S203= | Silent (SNP) | VAF 5/13 reads (38%) | catalogued as rs1384792098, COSV100824604; called by muse, mutect2, varscan2
- CDC34 | c.429C>T p.D143= | Silent (SNP) | VAF 13/99 reads (13%) | catalogued as rs772447667; called by muse, mutect2, varscan2
- CDKN2AIPNL | c.129C>T p.F43= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as rs755574360; called by muse, mutect2, varscan2
- DISP3 | c.189C>A p.T63= | Silent (SNP) | VAF 10/47 reads (21%) | called by muse, mutect2, varscan2
- FAM160B2 | c.1972C>T p.L658= | Silent (SNP) | VAF 11/65 reads (17%) | catalogued as rs745708606; called by muse, mutect2, varscan2
- GPRC6A | c.1209C>T p.L403= | Silent (SNP) | VAF 8/78 reads (10%) | called by muse, mutect2, varscan2
- KCNH2 | c.2328C>T p.L776= | Silent (SNP) | VAF 8/65 reads (12%) | called by muse, mutect2, varscan2
- MC4R | c.921A>G p.Q307= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as COSV100235843; called by muse, mutect2, varscan2
- NPY2R | c.333C>G p.T111= | Silent (SNP) | VAF 3/27 reads (11%) | called by muse, mutect2
- PCDHB4 | c.750C>A p.V250= | Silent (SNP) | VAF 6/37 reads (16%) | called by muse, mutect2, varscan2
- PRAMEF4 | c.360A>G p.E120= | Silent (SNP) | VAF 21/220 reads (10%) | called by muse, mutect2
- RASGEF1C | c.111G>A p.A37= | Silent (SNP) | VAF 9/33 reads (27%) | catalogued as rs766302866; called by muse, mutect2, varscan2
- SEMA4A | c.690C>T p.D230= | Silent (SNP) | VAF 5/28 reads (18%) | catalogued as rs763391247, COSV61772868; called by muse, mutect2, varscan2
- SIM2 | c.882C>T p.Y294= | Silent (SNP) | VAF 4/66 reads (6%) | called by muse, mutect2
- ST6GALNAC3 | c.681C>T p.D227= | Silent (SNP) | VAF 8/56 reads (14%) | catalogued as rs1297794903; called by muse, mutect2, varscan2
- STK16 | c.357C>T p.F119= | Silent (SNP) | VAF 6/75 reads (8%) | called by muse, mutect2
- WDR17 | c.1437A>T p.G479= | Silent (SNP) | VAF 4/39 reads (10%) | called by muse, mutect2, varscan2
- ZNF256 | c.1869C>T p.N623= | Silent (SNP) | VAF 16/113 reads (14%) | catalogued as rs749187734; called by muse, mutect2, varscan2
- AC017104.4 | chr2:231509208 C>T | 5'Flank (SNP) | VAF 7/68 reads (10%) | called by muse, mutect2, varscan2
- MIR154 | n.63T>G | RNA (SNP) | VAF 11/73 reads (15%) | called by muse, mutect2, varscan2
